CPTAC case C3L-06766 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aab2dce5-b3ba-4054-b157-23f50833c434

Demographics
Sex at birth: male; Race: white; Year of birth: 1970; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Fundus of stomach; Age at diagnosis: 50.0 years (18,266 days); Year of diagnosis: 2020; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Residual disease: RX; Days to last known disease status: 390 days (1.1 years); Progression or recurrence: no; Days to last follow up: 390 days (1.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 9 cm; Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 12.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 390.

Exposures
- Tobacco smoking status: Current Smoker; Cigarettes per day: 10; Alcohol history: Yes; Alcohol intensity: Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-06766-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 2 days; Initial weight: 600 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide CPT039441 0001: Section location: Fundus; Percent tumor nuclei: 70; Percent necrosis: 5.
- Sample C3L-06766-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 2 days; Initial weight: 500 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-06766-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 3 days; Method of sample procurement: Blood Draw.
